Somatic mutation profile of tumor specimen TCGA-BS-A0TA-01A (aliquot TCGA-BS-A0TA-01A-11D-A10B-09) from TCGA case TCGA-BS-A0TA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 58.9 years (21,505 days).
Specimen TCGA-BS-A0TA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e2577fd-8e73-4815-b3d3-7b61a60838b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0TA-10A (Blood Derived Normal), aliquot TCGA-BS-A0TA-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60235767-9d43-4854-8806-1484d3b2e4ea

The open-access MAF lists 593 somatic variants for this specimen: 458 protein-altering or splice-affecting, 123 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 307, Silent 123, Frame Shift Del 92, Nonsense Mutation 19, Frame Shift Ins 18, Splice Site 13, Splice Region 6, Intron 4, In Frame Del 3, 3'UTR 3, RNA 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 38/193 reads (20%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1350_1364del p.H450_T454del (on ENST00000521381 / NM_181523.3; = p.H180_T184del on NM_181504.4) | In Frame Del (DEL) | VAF 12/82 reads (15%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 20/67 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM115947, CM971272, COSV64289566, COSV64291659; called by muse, mutect2, varscan2
- ABCA3 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as rs367773869; called by muse, mutect2
- ABCB1 | c.287-1G>T p.X96_splice | Splice Site (SNP) | VAF 16/109 reads (15%) | catalogued as COSV55965076; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC6 | c.1780-1G>T p.X594_splice | Splice Site (SNP) | VAF 4/43 reads (9%) | catalogued as COSV52748359; called by muse, mutect2
- ABCG1 | c.1540C>A p.P514T | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.893); catalogued as COSV59211139; called by muse, mutect2, varscan2
- ABR | c.898C>T p.R300* (on ENST00000302538 / NM_021962.5; = p.R263* on NM_001092.5) | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as rs1403369396, COSV52152595; called by muse, mutect2
- ACD | c.1150C>T p.P384S (on ENST00000620338; = p.P295S on NM_022914.3) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as COSV54670785; called by muse, mutect2, varscan2
- ACR | c.968A>G p.H323R | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53362128; called by muse, mutect2
- ACSBG1 | c.325T>C p.F109L | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.147); catalogued as COSV51911512; called by muse, mutect2
- ACSL6 | c.1964C>T p.A655V (on ENST00000379240; = p.A680V on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs1414476151, COSV57305838; called by muse, mutect2, varscan2
- ADAM30 | c.844del p.S282Vfs*3 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | catalogued as rs757984494, COSV65561192; called by mutect2, pindel, varscan2
- ADAM8 | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV69865383; called by muse, mutect2, varscan2
- ADAMTS5 | c.2018G>A p.G673D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV53186101; called by muse, mutect2, varscan2
- ADAMTS9 | c.1706G>T p.G569V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV55774537, COSV55792034; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2532G>T p.Q844H | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.82); catalogued as rs1050540157, COSV54472747; called by muse, mutect2
- ADRA2A | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54530336; called by muse, mutect2, varscan2
- AGXT2 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV51491167, COSV99183952; called by muse, mutect2
- AHCY | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.377); catalogued as rs766897311, COSV54153242; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- ALDH2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs773061919, COSV55672145; called by muse, mutect2
- ALG8 | c.674-1G>T p.X225_splice | Splice Site (SNP) | VAF 15/78 reads (19%) | catalogued as COSV55203438; called by muse, mutect2, varscan2
- ALPK1 | c.1756T>G p.L586V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.176); catalogued as COSV51587682, COSV51592800; called by muse, mutect2
- ALPL | c.509A>G p.N170S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as COSV66381028; called by muse, mutect2
- ANK2 | c.10367dup p.T3457Hfs*8 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | catalogued as rs750143580; called by mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4240G>A p.V1414M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51859969; called by muse, mutect2, varscan2
- ANKRD28 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV67516891; called by muse, mutect2, varscan2
- ANKRD44 | c.2816del p.N939Ifs*16 | Frame Shift Del (DEL) | VAF 15/121 reads (12%) | catalogued as rs1408961377; called by mutect2, pindel, varscan2
- ANXA5 | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV56640383; called by muse, mutect2, varscan2
- AOC1 | c.2222del p.P741Lfs*54 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs999461756; called by mutect2, varscan2
- APOA2 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV57156320; called by muse, mutect2, varscan2
- ARHGAP27 | c.1513C>T p.R505C (on ENST00000428638 / NM_001282290.1; = p.R164C on NM_199282.3) | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); catalogued as rs759649387, COSV65358871; called by muse, varscan2
- ARID1A | c.2402del p.G801Vfs*32 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as COSV61388445; called by mutect2, pindel, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 12/63 reads (19%) | catalogued as rs758608743; called by mutect2, varscan2
- ARMC5 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.168); catalogued as rs769109228, COSV51660342; called by muse, varscan2
- ARSH | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369096338, COSV66962770; called by muse, mutect2, varscan2
- ASXL2 | c.3944A>G p.K1315R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV55468949; called by muse, mutect2
- ATAD2B | c.920del p.K307Rfs*57 | Frame Shift Del (DEL) | VAF 36/220 reads (16%) | catalogued as rs1558707706; called by mutect2, varscan2
- ATP10D | c.1848del p.L617Cfs*41 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs764067652, COSV56705401; called by mutect2, pindel
- ATP13A1 | c.3397C>G p.P1133A | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as COSV52291895; called by muse, mutect2, varscan2
- AVIL | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs1009088495, COSV57684097; called by muse, mutect2
- BAIAP2 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283746976, COSV58341346; called by muse, mutect2
- BCORL1 | c.3286G>A p.V1096I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.031); catalogued as rs751056161, COSV54388855, COSV54409042; called by muse, mutect2, varscan2
- BOC | c.646A>G p.S216G | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1395480707, COSV56358757; called by muse, mutect2, varscan2
- BOLA1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); catalogued as rs782649667, COSV64967708; called by muse, mutect2
- BRAF | c.1328dup p.A444Cfs*9 (on ENST00000288602 / NM_001374244.1; = p.A404Cfs*9 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 12/78 reads (15%) | catalogued as rs777474487; called by mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 14/44 reads (32%) | catalogued as rs749043197; called by mutect2, varscan2
- C10orf120 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs531792820, COSV61492799; called by muse, mutect2, varscan2
- C10orf88 | c.401del p.N134Ifs*2 | Frame Shift Del (DEL) | VAF 40/169 reads (24%) | catalogued as rs751388819; called by mutect2, varscan2
- C12orf56 | c.1286G>A p.R429H (on ENST00000543942 / NM_001170633.2; = p.R269H on NM_001099676.3) | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs375758649, COSV61485801; called by muse, mutect2, varscan2
- C16orf46 | c.116dup p.N39Kfs*11 | Frame Shift Ins (INS) | VAF 34/194 reads (18%) | catalogued as rs753533248; called by mutect2, varscan2
- C17orf98 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs764504486; called by muse, varscan2
- C2orf16 | c.4996T>G p.S1666A | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV62678750; called by muse, mutect2
- C8orf34 | c.1037T>C p.I346T | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs1563513026, COSV61399066; called by muse, mutect2, varscan2
- CACNA1S | c.2490+2T>C p.X830_splice | Splice Site (SNP) | VAF 18/86 reads (21%) | catalogued as COSV62944497; called by muse, mutect2, varscan2
- CASP8 | c.550+1G>A p.X184_splice (on ENST00000432109 / NM_033355.3; = p.X216_splice on NM_001228.4) | Splice Site (SNP) | VAF 12/89 reads (13%) | catalogued as COSV51860629; called by muse, mutect2, varscan2
- CCDC180 | c.4918C>T p.R1640C | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as rs140650703; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 31/161 reads (19%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 38/170 reads (22%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC51 | c.476A>G p.Q159R | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs775979259, COSV56494727; called by muse, mutect2
- CCDC74A | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.281); catalogued as COSV54609423; called by muse, mutect2
- CCDC88A | c.2335del p.I779Sfs*4 | Frame Shift Del (DEL) | VAF 12/142 reads (8%) | catalogued as COSV55059558; called by mutect2, pindel
- CCDC97 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.041); catalogued as rs1286685402, COSV54189870; called by muse, mutect2
- CCND1 | c.497C>A p.S166Y | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV57123590; called by muse, mutect2
- CCT3 | c.1610G>T p.G537V | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV55291831; called by muse, mutect2, varscan2
- CCT8L2 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.634); catalogued as rs1263893382, COSV63463986; called by muse, mutect2, varscan2
- CD5L | c.452_455del p.V151Efs*2 | Frame Shift Del (DEL) | VAF 9/83 reads (11%) | catalogued as COSV63823319; called by mutect2, pindel, varscan2
- CDC27 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV50702823; called by muse, mutect2, varscan2
- CDC42BPA | c.3741A>T p.E1247D (on ENST00000334218 / NM_001366019.2; = p.E1234D on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.253); catalogued as COSV62023402; called by muse, mutect2
- CDR2L | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.724); catalogued as rs368260807; called by muse, mutect2
- CDX2 | c.916del p.V306Cfs*2 | Frame Shift Del (DEL) | VAF 20/122 reads (16%) | catalogued as rs773511514; called by mutect2, pindel, varscan2
- CEP131 | c.1193-2A>C p.X398_splice | Splice Site (SNP) | VAF 16/62 reads (26%) | catalogued as COSV53956872, COSV99487886; called by muse, mutect2, varscan2
- CFAP43 | c.2914A>G p.S972G | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV53381890; called by muse, mutect2
- CFAP53 | c.719G>T p.S240I | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.351); catalogued as COSV68352954; called by muse, mutect2, varscan2
- CGNL1 | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV55576369; called by muse, mutect2, varscan2
- CHSY1 | c.1780T>C p.Y594H | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); catalogued as COSV54256414; called by muse, mutect2
- CIDEC | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1414656804, COSV100396654, COSV61062645; called by muse, mutect2, varscan2
- CILP2 | c.957del p.M320Cfs*74 | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | catalogued as rs759895052; called by mutect2, pindel, varscan2
- CLCN2 | c.1540A>G p.T514A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV55604747; called by muse, mutect2
- CLTCL1 | c.2893C>A p.P965T | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.232); catalogued as COSV54233863, COSV54240478; called by muse, mutect2, varscan2
- CMTM1 | c.180del p.F60Lfs*3 (on ENST00000457188 / NM_181269.3; = p.F177Lfs*3 on NM_052999.4) | Frame Shift Del (DEL) | VAF 41/234 reads (18%) | catalogued as rs773521289; called by mutect2, varscan2
- COL11A1 | c.1421del p.P474Qfs*20 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as COSV100617959, COSV62199128; called by mutect2, pindel
- COL6A2 | c.928-2A>G p.X310_splice | Splice Site (SNP) | VAF 5/50 reads (10%) | catalogued as rs1440070681, COSV56017612; called by muse, mutect2
- CPS1 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs187860166, COSV51807652; called by muse, mutect2, varscan2
- CRACDL | c.389G>T p.C130F | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.833); catalogued as COSV67410388; called by muse, mutect2, varscan2
- CRADD | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs138134122; called by muse, mutect2, varscan2
- CREBBP | c.4996G>A p.A1666T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as rs1159046430, COSV52143180; called by muse, mutect2, varscan2
- CRYGD | c.252C>T p.H84= | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as rs775032143, COSV52206246; called by muse, mutect2
- CSMD2 | c.7367G>A p.R2456Q | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs867709818, COSV53952924; called by muse, mutect2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | catalogued as rs766438669; called by pindel, varscan2
- CSNK1A1 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55793532, COSV55798554, COSV55798870; called by muse, mutect2, varscan2
- CTC1 | c.2335A>G p.T779A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV59855746; called by muse, mutect2
- CYB5R2 | c.433del p.T145Hfs*8 | Frame Shift Del (DEL) | VAF 55/295 reads (19%) | catalogued as rs775988957; called by mutect2, pindel, varscan2
- CYP3A5 | c.784A>G p.N262D | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV56123493; called by muse, mutect2, varscan2
- DAXX | c.1884dup p.C629Lfs*29 | Frame Shift Ins (INS) | VAF 22/129 reads (17%) | catalogued as rs1268651006; called by mutect2, pindel, varscan2
- DCAF4L2 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60476386, COSV60476821; called by muse, mutect2
- DCC | c.3047C>T p.T1016I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746093132, COSV59140551; called by muse, mutect2, varscan2
- DCHS1 | c.5263C>A p.H1755N | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV55043745; called by muse, mutect2, varscan2
- DCHS1 | c.1448C>A p.P483H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55043758; called by muse, mutect2
- DCK | c.307A>G p.S103G | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54380068; called by muse, mutect2
- DCLK3 | c.327del p.R110Gfs*69 | Frame Shift Del (DEL) | VAF 45/210 reads (21%) | catalogued as COSV101373865, COSV69362732; called by mutect2, pindel, varscan2
- DDX31 | c.2120G>T p.R707M | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV64651983; called by muse, mutect2
- DHX34 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs748157892, COSV60898628; called by muse, mutect2, varscan2
- DHX37 | c.2566A>G p.M856V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV58139800; called by muse, mutect2
- DHX57 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.98); catalogued as COSV54892018; called by muse, mutect2, varscan2
- DHX8 | c.3061C>T p.P1021S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52257008, COSV99291877; called by muse, mutect2, varscan2
- DIO3 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63773174; called by muse, varscan2
- DISP3 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs576336989, COSV53829175, COSV99037595; called by muse, mutect2, varscan2
- DMAC2 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.386); catalogued as rs782113187, COSV55729922; called by muse, mutect2
- DNAH10 | c.7160C>T p.A2387V (on ENST00000409039; = p.A2326V on NM_207437.3) | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs767541523, COSV69003640; called by muse, mutect2
- DNAH17 | c.12588+3A>G | Splice Region (SNP) | VAF 6/138 reads (4%) | catalogued as COSV99428268; called by muse, mutect2
- DNAJC18 | c.529A>G p.N177D | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV57416958; called by muse, mutect2, varscan2
- DNAJC21 | c.1496T>C p.V499A | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV57762965; called by muse, mutect2, varscan2
- DOCK11 | c.4604T>C p.L1535P | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52248687; called by muse, mutect2, varscan2
- DUOX1 | c.4178C>T p.T1393I | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52053013; called by muse, mutect2, varscan2
- DVL3 | c.1747A>G p.S583G | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.042); catalogued as COSV53050464; called by muse, mutect2, varscan2
- ECEL1 | c.1823C>T p.T608I | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs753195318, COSV58814495; called by muse, mutect2
- ECI1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs376899686; called by muse, mutect2, varscan2
- EFCAB5 | c.4249A>G p.N1417D | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.029); catalogued as COSV57938611; called by muse, mutect2, varscan2
- EFR3A | c.2462A>G p.Y821C | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54463066; called by muse, mutect2, varscan2
- EIF2AK3 | c.1745dup p.N582Kfs*11 | Frame Shift Ins (INS) | VAF 17/77 reads (22%) | catalogued as rs776056726; called by mutect2, pindel, varscan2
- EIF3M | c.800-1G>T p.X267_splice | Splice Site (SNP) | VAF 13/97 reads (13%) | catalogued as COSV58805713; called by muse, mutect2, varscan2
- ELP5 | c.361A>G p.I121V | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV59709352; called by muse, mutect2
- ENGASE | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs765743001, COSV56134874; called by muse, mutect2, varscan2
- ENTPD5 | c.586G>T p.G196W | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58224293; called by muse, mutect2, varscan2
- EP300 | c.4189T>G p.Y1397D | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54331943, COSV54346923; called by muse, mutect2, varscan2
- EPB41L1 | c.440G>A p.S147N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV52445978; called by muse, mutect2
- ERG28 | c.389T>G p.V130G | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53164793; called by muse, mutect2
- ESR1 | c.571T>C p.Y191H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV52803661; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as rs775950025; called by mutect2, varscan2
- EWSR1 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs772636858, COSV100132071, COSV58421516; called by muse, mutect2, varscan2
- F2R | c.292A>G p.S98G | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV59930376; called by muse, mutect2, varscan2
- FAM118B | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as rs1215013926, COSV64157309; called by muse, mutect2, varscan2
- FAM214B | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59717767; called by muse, mutect2, varscan2
- FASN | c.6097A>G p.N2033D | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV60762027; called by muse, mutect2
- FBXO30 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV52792671; called by muse, mutect2, varscan2
- FIGNL1 | c.77G>A p.C26Y | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV63554160; called by muse, mutect2, varscan2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | catalogued as COSV58769165; called by mutect2, varscan2
- FLNA | c.6531G>T p.Q2177H (on ENST00000369850 / NM_001110556.2; = p.Q2169H on NM_001456.3) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.161); catalogued as COSV61052883; called by muse, mutect2, varscan2
- FLNC | c.3593T>C p.V1198A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57966333; called by muse, mutect2
- FREM1 | c.3497T>G p.L1166R | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66531259; called by muse, mutect2
- FRMD4A | c.1266G>T p.K422N | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV52737552; called by muse, mutect2
- FRMD6 | c.925C>T p.R309C (on ENST00000344768 / NM_001267046.2; = p.R301C on NM_152330.4) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61090055; called by muse, mutect2, varscan2
- G6PC3 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 55/260 reads (21%) | catalogued as rs1056739194, CM1412545, COSV52244020; called by muse, mutect2, varscan2
- GBP2 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as rs200077424, COSV65068494; called by muse, mutect2
- GCKR | c.684A>C p.Q228H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.183); catalogued as COSV53111258; called by muse, mutect2
- GCSAM | c.105G>T p.W35C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV58264705; called by muse, mutect2, varscan2
- GFRAL | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61236183; called by muse, mutect2, varscan2
- GMIP | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52291885; called by muse, mutect2, varscan2
- GNAZ | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50742618; called by muse, mutect2
- GNL3 | c.1636A>G p.T546A | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV99803820; called by muse, mutect2
- GON4L | c.6415G>A p.V2139M | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55205716; called by muse, mutect2, varscan2
- GOT2 | c.271A>G p.N91D | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV55333707; called by muse, mutect2, varscan2
- GPR174 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.534); catalogued as COSV52134653; called by muse, mutect2, varscan2
- GPR176 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs755366702, COSV54448048; called by muse, mutect2, varscan2
- GPR62 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs749143927, COSV59056461; called by muse, mutect2, varscan2
- GPT2 | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV60838736; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | catalogued as rs754199513; called by mutect2, varscan2
- GZMB | c.572A>G p.D191G | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV53543864; called by muse, mutect2, varscan2
- HCN1 | c.1534del p.M512Cfs*19 | Frame Shift Del (DEL) | VAF 17/69 reads (25%) | catalogued as rs772669067; called by mutect2, pindel, varscan2
- HDAC4 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61878052; called by muse, mutect2, varscan2
- HEATR5A | c.3509G>A p.W1170* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV66346262; called by muse, mutect2, varscan2
- HEPH | c.476del p.G159Afs*31 (on ENST00000343002; = p.G213Afs*31 on NM_138737.5) | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | catalogued as COSV57967829, COSV57968004; called by mutect2, pindel, varscan2
- HEYL | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.09); catalogued as rs762466594, COSV65722132; called by muse, mutect2, varscan2
- HMBOX1 | c.1121A>G p.E374G | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV55072603; called by muse, mutect2, varscan2
- HMGN5 | c.404A>G p.E135G | Missense Mutation (SNP) | VAF 69/450 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV63918482; called by muse, mutect2, varscan2
- HOXA3 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57825122, COSV57826336; called by muse, mutect2
- IARS2 | c.2645C>T p.A882V | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.585); catalogued as rs367582125; called by muse, mutect2, varscan2
- IGFALS | c.727C>G p.R243G | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.57); catalogued as rs748347228, COSV51908846; called by muse, mutect2
- IL12A | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV59760291; called by muse, mutect2, varscan2
- IL23R | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as rs758690026, COSV61373282; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 15/117 reads (13%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IQGAP3 | c.3922del p.L1308Cfs*30 | Frame Shift Del (DEL) | VAF 18/89 reads (20%) | catalogued as rs1159514618; called by mutect2, varscan2
- JMJD7-PLA2G4B | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 53/301 reads (18%) | catalogued as rs748739295, COSV59828937; called by muse, mutect2, varscan2
- KANSL3 | c.332G>T p.R111M | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62624125; called by muse, mutect2, varscan2
- KCNH4 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52921449, COSV52921524; called by muse, mutect2, varscan2
- KCNJ13 | c.128A>C p.D43A | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52086176; called by muse, mutect2, varscan2
- KCNQ5 | c.573G>T p.W191C | Missense Mutation (SNP) | VAF 57/292 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59685292; called by muse, mutect2, varscan2
- KCNV1 | c.944G>T p.R315M | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV52089462; called by muse, mutect2, varscan2
- KCTD18 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs765871188, COSV63344017, COSV63344257, COSV63344277; called by muse, mutect2
- KEAP1 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs539818436, COSV50294747; called by muse, mutect2, varscan2
- KIDINS220 | c.4063C>T p.R1355C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.776); catalogued as rs756204802, COSV56750278; called by muse, mutect2
- KLF3 | c.781A>G p.R261G | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV54710852, COSV54712879; called by muse, mutect2, varscan2
- KLHL9 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV62922499; called by muse, mutect2, varscan2
- KMT2C | c.6082C>T p.R2028* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as rs1563288201, COSV51467980; called by muse, mutect2, varscan2
- KMT2D | c.15460C>T p.R5154W | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768551828, COSV56424929; called by muse, mutect2
- KMT2D | c.9596G>A p.S3199N | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1232234078, COSV56416472; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KPNB1 | c.1702A>G p.I568V | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV51601049; called by muse, mutect2, varscan2
- KRT16 | c.197del p.G66Afs*54 | Frame Shift Del (DEL) | VAF 45/236 reads (19%) | catalogued as rs1555573913; called by mutect2, pindel, varscan2
- LAMA2 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV70356280, COSV70358148; called by muse, mutect2
- LRCH1 | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs1251708213, COSV60844141; called by muse, mutect2, varscan2
- LRP1 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV54527149; called by muse, mutect2
- LRP2 | c.2879T>C p.L960S | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV55577585; called by muse, mutect2, varscan2
- LRRC4 | c.1849C>A p.H617N | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV50819483; called by muse, mutect2
- LRRC4 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV50819521; called by muse, mutect2, varscan2
- LRRC66 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751669990, COSV58633914, COSV58637046; called by muse, mutect2, varscan2
- MAD1L1 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.373); catalogued as rs1478926866, COSV56249577; called by muse, mutect2
- MAP1A | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201398891, COSV55807797; called by muse, mutect2, varscan2
- MAP3K3 | c.1841A>T p.E614V | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV51992828; called by muse, mutect2
- MAP4 | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs776422902, COSV64245174; called by muse, mutect2, varscan2
- MAST2 | c.3820del p.R1274Dfs*9 | Frame Shift Del (DEL) | VAF 33/157 reads (21%) | catalogued as rs1405419593; called by mutect2, pindel, varscan2
- MCOLN3 | c.1226T>C p.L409P | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62016558; called by muse, mutect2, varscan2
- MDN1 | c.12868C>A p.L4290M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV65531538; called by muse, mutect2
- ME1 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.072); catalogued as COSV63842993; called by muse, mutect2, varscan2
- METTL17 | c.118A>G p.K40E | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV59556958; called by muse, mutect2, varscan2
- MGA | c.7401C>A p.A2467= (on ENST00000219905 / NM_001164273.1; = p.A2258= on NM_001080541.2) | Splice Region (SNP) | VAF 12/67 reads (18%) | catalogued as COSV54964330; called by muse, mutect2, varscan2
- MICAL3 | c.3352C>T p.R1118C | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.249); catalogued as rs769551274, COSV71588825; called by muse, mutect2
- MMEL1 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as rs1336716532, COSV56526898; called by muse, mutect2, varscan2
- MPG | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs112187829; called by muse, mutect2, varscan2
- MROH2B | c.682G>T p.G228* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV101270569, COSV68183631; called by muse, mutect2, varscan2
- MRPL43 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV52972587; called by muse, mutect2
- MRPL50 | c.450dup p.N151Qfs*24 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | catalogued as rs755588721; called by mutect2, pindel, varscan2
- MRPS30 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs534375825, COSV50181666; called by muse, mutect2, varscan2
- MSANTD4 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.986); catalogued as COSV57287067; called by muse, mutect2, varscan2
- MYBL2 | c.316T>C p.W106R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53834232; called by muse, mutect2, varscan2
- MYF6 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1234740280, COSV57353681; called by muse, mutect2, varscan2
- MYH9 | c.3586C>T p.Q1196* | Nonsense Mutation (SNP) | VAF 24/124 reads (19%) | catalogued as COSV53394204; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO6 | c.1522T>C p.Y508H | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64121783; called by muse, mutect2, varscan2
- MYOCD | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV58506469, COSV58513507; called by muse, mutect2, varscan2
- NAGS | c.1594C>A p.P532T | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV52814341; called by muse, mutect2
- NEMP1 | c.844T>C p.W282R (on ENST00000300128 / NM_001130963.2; = p.W209R on NM_015257.3) | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55664887; called by muse, mutect2, varscan2
- NEUROD4 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54474497; called by muse, mutect2, varscan2
- NF1 | c.4022A>C p.Q1341P | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.433); catalogued as COSV62223849; called by muse, mutect2
- NFKB2 | c.2668C>T p.L890F (on ENST00000369966 / NM_001322935.1; = p.L889F on NM_002502.6) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.916); catalogued as COSV50065609; called by muse, mutect2, varscan2
- NHLH1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV57484484; called by muse, mutect2, varscan2
- NIBAN2 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV64823851; called by muse, mutect2
- NOBOX | c.628A>G p.N210D | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs372071820; called by muse, mutect2, varscan2
- NPHP4 | c.3365C>A p.T1122N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as COSV65398476; called by muse, mutect2
- NSA2 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as COSV57189141; called by muse, mutect2, varscan2
- NSD1 | c.5423A>G p.H1808R | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV61785987; called by muse, mutect2, varscan2
- NSG2 | c.214-2A>G p.X72_splice | Splice Site (SNP) | VAF 56/272 reads (21%) | catalogued as COSV100292840, COSV57460068; called by muse, mutect2, varscan2
- NT5C2 | c.1534G>C p.V512L | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV58419755; called by muse, mutect2, varscan2
- NUDT17 | c.378T>C p.G126= | Splice Region (SNP) | VAF 6/66 reads (9%) | catalogued as COSV57908793; called by muse, mutect2
- NUP107 | c.1574A>G p.D525G | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57498618; called by muse, mutect2
- NWD1 | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV60353085; called by muse, mutect2, varscan2
- OGDHL | c.1043T>G p.V348G | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as COSV100934330, COSV65105032; called by muse, mutect2
- OPN5 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.04); catalogued as rs150978153; called by muse, mutect2, varscan2
- OR11G2 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs376091395, COSV62133253; called by muse, mutect2, varscan2
- OR5D13 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs777852254, COSV100686654, COSV62332645; called by muse, mutect2, varscan2
- OR6C70 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.985); catalogued as rs140433772; called by muse, mutect2, varscan2
- OR7C1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs756541110, COSV50183626; called by muse, mutect2, varscan2
- OR9A2 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as rs200585126, COSV63307180; called by muse, mutect2
- OTUD7B | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs782028895, COSV64917989; called by muse, mutect2
- PAPOLG | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753313760, COSV53186170; called by muse, mutect2, varscan2
- PARP15 | c.1142G>A p.G381E (on ENST00000464300 / NM_001113523.3; = p.G147E on NM_152615.2) | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV59975368; called by muse, mutect2, varscan2
- PCDH11X | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.546); catalogued as COSV53509972; called by muse, mutect2
- PCDHA12 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV56551323; called by muse, mutect2, varscan2
- PCDHGB4 | c.1136A>G p.E379G | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV54046409; called by muse, mutect2, varscan2
- PDCD7 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV52601594; called by muse, mutect2
- PDZD2 | c.2219G>A p.G740D | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV56874774; called by muse, mutect2, varscan2
- PDZK1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV58260790; called by muse, mutect2, varscan2
- PEAR1 | c.1889G>A p.C630Y | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52776313; called by muse, mutect2
- PHF2 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.467); catalogued as rs778437718, COSV63678396; called by muse, mutect2
- PHKB | c.1692+2T>C p.X564_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | catalogued as COSV54535952; called by muse, mutect2
- PHLPP2 | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 82/408 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62427572; called by muse, mutect2, varscan2
- PIAS4 | c.743T>C p.L248P | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as rs747881688, COSV53681394; called by muse, mutect2, varscan2
- PIGT | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as rs766494019, COSV54129240; called by muse, mutect2, varscan2
- PITX3 | c.256T>C p.Y86H | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64175109; called by muse, mutect2
- PKD1L1 | c.5901C>A p.Y1967* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV56979889; called by muse, mutect2, varscan2
- PLAA | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 26/137 reads (19%) | catalogued as rs1211928080, COSV68305707; called by muse, mutect2, varscan2
- PLCE1 | c.4151del p.N1384Mfs*39 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as rs1564843502; called by mutect2, pindel, varscan2
- PLPP6 | c.865T>C p.F289L | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.344); catalogued as rs772266617, COSV56307388; called by muse, mutect2
- PMPCA | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs780097115, COSV53743758; called by muse, mutect2
- POLD3 | c.849dup p.S284Ifs*9 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | catalogued as rs1413278764; called by pindel, varscan2
- POP1 | c.815T>C p.I272T | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs754287651, COSV62894293; called by muse, mutect2, varscan2
- POTEE | c.908G>T p.R303I | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV58224851; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2276G>T p.R759M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.383); catalogued as COSV53456321; called by muse, mutect2, varscan2
- PPFIA4 | c.1900C>A p.L634M (on ENST00000447715; = p.L635M on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.593); catalogued as COSV55322318; called by muse, mutect2
- PPIF | c.569A>G p.K190R | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.006); catalogued as COSV56551724; called by muse, mutect2, varscan2
- PPL | c.1871G>T p.S624I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV62051541; called by muse, mutect2
- PPM1J | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.673); catalogued as COSV58552979; called by muse, mutect2, varscan2
- PPP6R3 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs201750404; called by muse, mutect2, varscan2
- PRAMEF1 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs267597970, COSV60019819; called by muse, mutect2, varscan2
- PRKDC | c.11158G>A p.A3720T | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs370811908; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 37/158 reads (23%) | catalogued as rs781858060; called by mutect2, varscan2
- PTCD1 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52868359; called by muse, mutect2, varscan2
- PXDNL | c.3322G>A p.A1108T | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV62500040; called by muse, mutect2, varscan2
- RASAL1 | c.2336T>G p.L779R | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV55660281; called by muse, mutect2, varscan2
- RBM45 | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53722765; called by muse, mutect2
- RBSN | c.347A>G p.H116R | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.13); catalogued as rs921078459, COSV53795925; called by muse, mutect2
- RENBP | c.959T>C p.M320T | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64170706; called by muse, mutect2, varscan2
- RGL2 | c.1645T>C p.C549R | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV65843016; called by muse, mutect2
- RIC3 | c.907T>C p.C303R (on ENST00000309737 / NM_001206671.4; = p.C302R on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as rs368357944; called by muse, mutect2, varscan2
- RNF141 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56418079; called by muse, mutect2
- RSPO3 | c.415A>G p.T139A | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV63153360; called by muse, mutect2, varscan2
- RTL4 | c.731T>C p.L244P | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.648); catalogued as COSV61207438; called by muse, mutect2, varscan2
- RUFY2 | c.457del p.M153Wfs*8 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | catalogued as rs759904440; called by mutect2, varscan2
- RYR3 | c.9205A>G p.T3069A (on ENST00000389232; = p.T3070A on NM_001036.6) | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV66810263; called by muse, mutect2, varscan2
- SAC3D1 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100100823, COSV57248678; called by muse, mutect2
- SACS | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs867805312, COSV66547584; called by muse, mutect2, varscan2
- SAFB2 | c.2349G>A p.R783= | Splice Region (SNP) | VAF 9/113 reads (8%) | catalogued as COSV53041036; called by muse, mutect2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SALL4 | c.496del p.Q166Rfs*3 | Frame Shift Del (DEL) | VAF 18/117 reads (15%) | catalogued as CM042108; called by mutect2, pindel, varscan2
- SART3 | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV57210941; called by muse, mutect2
- SATB1 | c.1817A>G p.Q606R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.05); catalogued as COSV58673211; called by muse, mutect2, varscan2
- SCPEP1 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51855813; called by muse, mutect2
- SDHA | c.376A>C p.T126P | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53774316; called by muse, mutect2, varscan2
- SDHA | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.333); catalogued as COSV53774350; called by muse, mutect2, varscan2
- SEC24C | c.1838G>T p.R613M | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV59545348; called by muse, mutect2, varscan2
- SEPTIN6 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 106/514 reads (21%) | catalogued as COSV59718106; called by muse, mutect2, varscan2
- SERINC1 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60103004; called by muse, mutect2
- SGSM1 | c.3361A>G p.M1121V (on ENST00000400359 / NM_001039948.4; = p.M1060V on NM_133454.3) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV68514148; called by muse, mutect2, varscan2
- SH3BP2 | c.285del p.F96Sfs*103 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as COSV62554374; called by mutect2, varscan2
- SH3KBP1 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs776375600, COSV65650344; called by muse, mutect2, varscan2
- SHBG | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs771580906, COSV52648014; called by muse, mutect2, varscan2
- SHMT1 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs774151028, COSV57400839; called by muse, mutect2
- SHROOM3 | c.4696G>T p.G1566W | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV56040755; called by muse, mutect2
- SIAH1 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53526784; called by muse, mutect2, varscan2
- SLC22A13 | c.1300A>G p.T434A | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); catalogued as COSV61292326; called by muse, mutect2, varscan2
- SLC22A8 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV60327445; called by muse, mutect2, varscan2
- SLC23A3 | c.709C>A p.L237M (on ENST00000409878 / NM_001144889.2; = p.T226= on NM_144712.5) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55409857; called by muse, mutect2, varscan2
- SLC25A4 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55668969; called by muse, mutect2
- SLC6A11 | c.314dup p.L106Pfs*11 | Frame Shift Ins (INS) | VAF 65/365 reads (18%) | catalogued as rs1210471783; called by mutect2, varscan2
- SLC6A6 | c.1612T>C p.Y538H | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62653251; called by muse, mutect2
- SLIT1 | c.1915G>A p.V639I | Missense Mutation (SNP) | VAF 77/363 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs777884062, COSV56582282, COSV56600651; called by muse, mutect2, varscan2
- SMTNL1 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1422460152, COSV67700821; called by muse, mutect2, varscan2
- SOAT2 | c.812A>G p.Y271C | Missense Mutation (SNP) | VAF 72/403 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56861709; called by muse, mutect2, varscan2
- SORCS3 | c.1952T>C p.V651A | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100863522, COSV63794452; called by muse, mutect2, varscan2
- SOS2 | c.3814C>T p.R1272C | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1005498417, COSV53567762, COSV53575599; called by muse, mutect2, varscan2
- SOX13 | c.1010del p.P337Rfs*69 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs1362904355; called by mutect2, varscan2
- SPATA18 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs772456267, COSV54651114; called by muse, mutect2, varscan2
- SPHKAP | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 27/181 reads (15%) | catalogued as COSV60896334; called by muse, mutect2, varscan2
- SPIN1 | c.589+2T>C p.X197_splice | Splice Site (SNP) | VAF 19/110 reads (17%) | catalogued as COSV65501370; called by muse, mutect2, varscan2
- SPOPL | c.960A>C p.Q320H | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV54516822; called by muse, mutect2, varscan2
- SPTBN5 | c.4806G>T p.Q1602H | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV58028949; called by muse, mutect2
- SRCAP | c.1896G>A p.M632I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV52682227; called by muse, mutect2, varscan2
- SRP54 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as COSV53741824; called by muse, mutect2, varscan2
- SSB | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53630435; called by muse, mutect2, varscan2
- STEAP3 | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.681); catalogued as rs767495306, COSV61528726; called by muse, mutect2
- STKLD1 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.556); catalogued as rs587672490, COSV64315058; called by muse, mutect2, varscan2
- STUB1 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.521); catalogued as rs1314944308, COSV50206213; called by muse, mutect2, varscan2
- SUGP2 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV58266240; called by muse, mutect2
- SYNE1 | c.23617A>G p.I7873V (on ENST00000367255 / NM_182961.4; = p.I7802V on NM_033071.3) | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.332); catalogued as rs1249661326, COSV55120098; called by muse, mutect2, varscan2
- SYNJ1 | c.4285C>T p.R1429* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as rs565341830, COSV59145247; called by muse, varscan2
- TASP1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.647); catalogued as COSV61816347; called by muse, mutect2, varscan2
- TBC1D25 | c.670A>G p.I224V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV65124784; called by muse, mutect2, varscan2
- TBC1D9 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs1255574879, COSV71309367; called by muse, mutect2, varscan2
- TCIRG1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as rs777437386, COSV55835624; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | catalogued as rs763321097; called by mutect2, varscan2
- THADA | c.3748C>G p.R1250G | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV57681467; called by muse, mutect2, varscan2
- THOC6 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 73/305 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs780072471, COSV50188313; called by muse, mutect2, varscan2
- TKTL1 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV54215325; called by muse, mutect2, varscan2
- TKTL1 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.209); catalogued as COSV54215334; called by muse, mutect2, varscan2
- TMEM132D | c.734G>A p.R245K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV70623753; called by muse, mutect2, varscan2
- TMEM97 | c.148T>C p.Y50H | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.38); catalogued as COSV56879954; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 18/79 reads (23%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNN | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs776425839, COSV53437237; called by muse, mutect2
- TNRC6A | c.5247T>A p.N1749K | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV59370805; called by muse, mutect2, varscan2
- TOP2B | c.278G>A p.C93Y (on ENST00000264331 / NM_001330700.2; = p.C88Y on NM_001068.3) | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763948503, COSV51977952; called by muse, mutect2, varscan2
- TP73 | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271961675, COSV60706647; called by muse, mutect2
- TPO | c.1705A>C p.N569H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV61112450; called by muse, mutect2
- TPRG1 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs745626174, COSV61469277; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 23/374 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.378); catalogued as COSV64854435; called by muse, mutect2
- TRIM32 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.439); catalogued as rs749689590, COSV57821661; called by muse, mutect2
- TRPM6 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1242699801, COSV62524335; called by mutect2, varscan2
- TRRAP | c.7993C>T p.R2665W (on ENST00000359863 / NM_001244580.1; = p.R2647W on NM_003496.3) | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62839851; called by muse, mutect2, varscan2
- TSPYL4 | c.1134G>A p.W378* | Nonsense Mutation (SNP) | VAF 33/177 reads (19%) | catalogued as COSV60313170; called by muse, mutect2, varscan2
- TTC21B | c.2671G>A p.A891T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373305833; called by muse, mutect2, varscan2
- TTN | c.90512G>A p.G30171D (on ENST00000591111; = p.G22747D on NM_003319.4) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | PolyPhen probably damaging (1); catalogued as rs942567175, COSV60387891; called by muse, mutect2
- TXNDC12 | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV57631423; called by muse, mutect2, varscan2
- TXNRD2 | c.1175A>G p.Y392C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs756375635, COSV68693500; called by muse, mutect2, varscan2
- TYK2 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV53389609; called by muse, mutect2, varscan2
- UACA | c.4133A>G p.Q1378R | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.993); catalogued as COSV59860649; called by muse, mutect2, varscan2
- UHRF2 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV52796627; called by muse, mutect2, varscan2
- UNC5A | c.1870-1G>A p.X624_splice | Splice Site (SNP) | VAF 7/40 reads (18%) | catalogued as COSV52845339; called by muse, mutect2
- USP12 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56660251; called by muse, mutect2, varscan2
- USP20 | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs781493140, COSV59619848; called by muse, mutect2
- USP32 | c.2840C>T p.T947I | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.173); catalogued as COSV56278466; called by muse, mutect2
- USP35 | c.3005del p.G1002Afs*25 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs748738592; called by mutect2, pindel, varscan2
- USP36 | c.3190C>T p.R1064W | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs763056095, COSV61754846; called by muse, mutect2, varscan2
- USP37 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV51447766; called by muse, varscan2
- USP42 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as rs374814529, COSV60357608; called by muse, mutect2, varscan2
- UTRN | c.4091T>C p.L1364P | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62349566; called by muse, mutect2, varscan2
- UVSSA | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758407459, COSV66229997; called by muse, mutect2, varscan2
- WARS2 | c.980A>G p.D327G | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV52483117; called by muse, mutect2, varscan2
- WDR3 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62525592; called by muse, mutect2, varscan2
- XPO5 | c.2216C>T p.T739I | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV54835826; called by muse, mutect2
- YTHDF2 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs2318770, COSV65722475; called by muse, mutect2, varscan2
- ZBTB47 | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1469918237, COSV51766135; called by muse, mutect2
- ZBTB7C | c.403del p.E135Rfs*87 | Frame Shift Del (DEL) | VAF 69/356 reads (19%) | catalogued as rs747456682, COSV59688820; called by mutect2, pindel, varscan2
- ZC3H12A | c.1030T>C p.S344P | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV66104617; called by muse, mutect2
- ZCCHC4 | c.960del p.F320Lfs*19 | Frame Shift Del (DEL) | VAF 20/121 reads (17%) | catalogued as rs760215323; called by mutect2, pindel, varscan2
- ZFAND4 | c.671T>C p.M224T | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60861823; called by muse, mutect2, varscan2
- ZFHX3 | c.2096del p.G699Afs*125 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | catalogued as rs753977275, COSV51729347; called by mutect2, varscan2
- ZNF330 | c.14del p.K5Rfs*18 | Frame Shift Del (DEL) | VAF 13/116 reads (11%) | catalogued as rs770975379; called by mutect2, varscan2
- ZNF354A | c.1625G>T p.R542M | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59985201; called by muse, mutect2
- ZNF470 | c.1730G>A p.G577D | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.242); catalogued as COSV57971030; called by muse, mutect2, varscan2
- ZNF606 | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58708264; called by muse, mutect2, varscan2
- ZNF613 | c.1261A>G p.T421A (on ENST00000293471 / NM_001031721.4; = p.T385A on NM_024840.4) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV53274303; called by muse, mutect2, varscan2
- ZNF665 | c.184C>T p.R62C (on ENST00000600412; = p.R127C on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as COSV67217488; called by muse, mutect2, varscan2
- ZNF792 | c.1505G>C p.G502A | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV68694568; called by muse, mutect2, varscan2
- ZNF793 | c.862del p.C288Vfs*113 | Frame Shift Del (DEL) | VAF 24/138 reads (17%) | catalogued as rs761241629, COSV101495729; called by mutect2, varscan2
- ZSCAN26 | c.874C>T p.Q292* (on ENST00000623276 / NM_001111039.2; = p.Q158* on NM_152736.5) | Nonsense Mutation (SNP) | VAF 26/153 reads (17%) | catalogued as rs1484160993, COSV57272189; called by muse, mutect2, varscan2
- ZXDA | c.1037A>C p.N346T | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62389006; called by muse, mutect2, varscan2
- AFDN | c.3041del p.K1014Sfs*20 | Frame Shift Del (DEL) | VAF 21/128 reads (16%) | called by mutect2, pindel, varscan2
- ARHGAP19 | c.839del p.N280Mfs*14 | Frame Shift Del (DEL) | VAF 69/407 reads (17%) | called by mutect2, pindel, varscan2
- ARHGAP36 | c.92del p.L31* | Frame Shift Del (DEL) | VAF 23/157 reads (15%) | called by mutect2, pindel, varscan2
- ASXL3 | c.2625del p.V876Cfs*59 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | called by mutect2, varscan2
- CASP8 | c.1419del p.K473Nfs*? (on ENST00000432109 / NM_033355.3; = p.K490Nfs*? on NM_001228.4) | Frame Shift Del (DEL) | VAF 43/220 reads (20%) | called by mutect2, pindel, varscan2
- CATSPERG | c.1403_1404del p.E468Vfs*15 | Frame Shift Del (DEL) | VAF 27/150 reads (18%) | called by pindel, varscan2
- CEACAM3 | c.454dup p.A152Gfs*36 | Frame Shift Ins (INS) | VAF 29/124 reads (23%) | called by mutect2, pindel, varscan2
- CELSR2 | c.6048del p.W2017Gfs*17 | Frame Shift Del (DEL) | VAF 29/152 reads (19%) | called by mutect2, pindel, varscan2
- CEP170 | c.1442del p.N481Ifs*26 | Frame Shift Del (DEL) | VAF 36/189 reads (19%) | called by mutect2, pindel, varscan2
- CGB8 | c.395A>G p.D132G | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.191); called by muse, mutect2
- COL25A1 | c.1719del p.G574Efs*36 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- DDX11 | c.820del p.S274Afs*2 | Frame Shift Del (DEL) | VAF 41/231 reads (18%) | called by mutect2, pindel, varscan2
- DLC1 | c.534_535del p.S178Rfs*7 | Frame Shift Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- DMTN | c.281del p.P94Hfs*137 | Frame Shift Del (DEL) | VAF 46/231 reads (20%) | called by mutect2, pindel, varscan2
- DNAJA2 | c.612del p.K204Nfs*7 | Frame Shift Del (DEL) | VAF 46/249 reads (18%) | called by mutect2, pindel, varscan2
- DNAJC21 | c.1247del p.K416Sfs*33 | Frame Shift Del (DEL) | VAF 35/142 reads (25%) | called by mutect2, pindel, varscan2
- EML5 | c.5848_5850del p.V1950del (on ENST00000380664; = p.V1958del on NM_183387.3) | In Frame Del (DEL) | VAF 14/84 reads (17%) | called by pindel, varscan2
- F13A1 | c.397del p.A133Pfs*5 | Frame Shift Del (DEL) | VAF 12/95 reads (13%) | called by mutect2, pindel, varscan2
- FAM160A2 | c.949del p.L317Wfs*31 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | called by mutect2, pindel, varscan2
- FREM2 | c.1046_1047del p.E349Vfs*4 | Frame Shift Del (DEL) | VAF 32/130 reads (25%) | called by mutect2, pindel, varscan2
- GATA3 | c.1131del p.V378Cfs*26 | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | called by mutect2, pindel, varscan2
- IRF6 | c.211dup p.V71Gfs*3 | Frame Shift Ins (INS) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- JAG1 | c.1845_1846del p.C615* | Nonsense Mutation (DEL) | VAF 23/138 reads (17%) | called by pindel, varscan2
- JAG1 | c.509_514del p.L170_K171del | In Frame Del (DEL) | VAF 28/135 reads (21%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 24/170 reads (14%) | called by mutect2, varscan2
- LAYN | c.664del p.T222Hfs*10 (on ENST00000375615 / NM_001258390.1; = p.T214Hfs*10 on NM_178834.5) | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- LOXL2 | c.1199dup p.S401Vfs*149 | Frame Shift Ins (INS) | VAF 33/170 reads (19%) | called by mutect2, pindel, varscan2
- MACROH2A2 | c.438del p.K147Rfs*53 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- MEGF8 | c.1593del p.Y532Tfs*9 | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | called by mutect2, pindel, varscan2
- MPRIP | c.1090del p.L364Cfs*19 | Frame Shift Del (DEL) | VAF 15/77 reads (19%) | called by mutect2, pindel, varscan2
- MVP | c.164del p.P55Hfs*69 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | called by mutect2, varscan2
- MYOF | c.4755del p.V1586Sfs*23 | Frame Shift Del (DEL) | VAF 51/248 reads (21%) | called by mutect2, pindel, varscan2
- NEXMIF | c.3334dup p.I1112Nfs*22 | Frame Shift Ins (INS) | VAF 7/68 reads (10%) | called by mutect2, pindel, varscan2
- NFXL1 | c.357del p.K119Nfs*11 | Frame Shift Del (DEL) | VAF 66/276 reads (24%) | called by mutect2, pindel, varscan2
- NOP58 | c.1571del p.K524Rfs*22 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, varscan2
- PARP4 | c.2541del p.K847Nfs*25 | Frame Shift Del (DEL) | VAF 13/115 reads (11%) | called by mutect2, pindel, varscan2
- PLIN2 | c.612del p.V205Lfs*55 | Frame Shift Del (DEL) | VAF 27/121 reads (22%) | called by mutect2, varscan2
- POLD3 | c.850_890delinsATCCAGCAAAAAAGCAGAGCCTGTTAAGGTGCTGCAGAAGG p.S284_E297delinsIQQKSRAC* | Nonsense Mutation (ONP) | VAF 6/45 reads (13%) | called by pindel, varscan2*
- PTEN | c.39_51del p.R15Mfs*5 | Frame Shift Del (DEL) | VAF 34/284 reads (12%) | called by mutect2, pindel
- RAB3GAP1 | c.2490+3_2490+6del p.X830_splice | Splice Site (DEL) | VAF 14/84 reads (17%) | called by pindel, varscan2
- RBM27 | c.2488del p.R830Dfs*5 | Frame Shift Del (DEL) | VAF 26/123 reads (21%) | called by mutect2, varscan2
- SCN10A | c.4669del p.S1557Lfs*30 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel
- SENP2 | c.65del p.P22Lfs*6 | Frame Shift Del (DEL) | VAF 22/118 reads (19%) | called by pindel, varscan2
- SLC11A2 | c.720del p.F240Lfs*19 (on ENST00000394904 / NM_001379455.1; = p.F211Lfs*19 on NM_000617.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- SLC26A9 | c.740del p.N247Tfs*23 | Frame Shift Del (DEL) | VAF 25/147 reads (17%) | called by mutect2, pindel, varscan2
- SLC5A2 | c.278dup p.L93Ffs*257 | Frame Shift Ins (INS) | VAF 28/182 reads (15%) | called by mutect2, pindel, varscan2
- SLC9A9 | c.89del p.L30Cfs*7 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- SORCS3 | c.3105dup p.V1036Sfs*39 | Frame Shift Ins (INS) | VAF 34/155 reads (22%) | called by mutect2, pindel, varscan2
- SOX5 | c.1916del p.K639Sfs*77 | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | called by mutect2, pindel, varscan2
- SUGP2 | c.688del p.E230Rfs*18 | Frame Shift Del (DEL) | VAF 36/188 reads (19%) | called by mutect2, pindel, varscan2
- TECTA | c.5373del p.Y1792Mfs*13 | Frame Shift Del (DEL) | VAF 40/214 reads (19%) | called by mutect2, pindel
- TEX10 | c.13del p.R5Efs*10 | Frame Shift Del (DEL) | VAF 61/303 reads (20%) | called by mutect2, pindel, varscan2
- TMEM50A | c.426del p.F142Lfs*20 | Frame Shift Del (DEL) | VAF 37/244 reads (15%) | called by mutect2, pindel, varscan2
- TNRC6A | c.2409del p.W804Gfs*99 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- TTN | c.91919del p.N30640Mfs*15 (on ENST00000591111; = p.N23216Mfs*15 on NM_003319.4) | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- UGT1A6 | c.1554del p.R522Efs*22 | Frame Shift Del (DEL) | VAF 31/179 reads (17%) | called by mutect2, pindel, varscan2
- UGT1A9 | c.677dup p.N226Kfs*8 | Frame Shift Ins (INS) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- WDFY3 | c.7148del p.K2383Rfs*51 | Frame Shift Del (DEL) | VAF 10/99 reads (10%) | called by mutect2, pindel, varscan2
- ZNF358 | c.1458dup p.S487Qfs*9 | Frame Shift Ins (INS) | VAF 22/100 reads (22%) | called by mutect2, pindel, varscan2
- ZNF462 | c.3502dup p.R1168Pfs*15 | Frame Shift Ins (INS) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- ABCA12 | c.4275G>A p.Q1425= (on ENST00000272895 / NM_173076.3; = p.Q1107= on NM_015657.3) | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as COSV55952509; called by muse, mutect2, varscan2
- ABCB1 | c.913C>T p.L305= | Silent (SNP) | VAF 61/262 reads (23%) | catalogued as COSV55965067; called by muse, mutect2, varscan2
- ADD1 | c.657C>T p.A219= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs752225325, COSV53275064; called by muse, mutect2, varscan2
- ADGRF5 | c.3624G>A p.K1208= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV51941265; called by muse, mutect2
- AIFM3 | c.666C>T p.I222= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs775433268, COSV58998555; called by muse, mutect2
- AMHR2 | c.618C>T p.S206= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV57687213; called by muse, mutect2, varscan2
- ANKZF1 | c.1434C>A p.P478= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV55479365; called by muse, mutect2, varscan2
- B4GALNT3 | c.2862C>T p.G954= | Silent (SNP) | VAF 31/149 reads (21%) | catalogued as rs200536520; called by muse, mutect2, varscan2
- BCOR | c.4014A>G p.E1338= (on ENST00000378444 / NM_001123385.2; = p.E1304= on NM_017745.6) | Silent (SNP) | VAF 61/378 reads (16%) | catalogued as COSV60720121; called by muse, mutect2, varscan2
- BLNK | c.840C>T p.R280= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV56415511; called by muse, mutect2, varscan2
- C1QTNF3 | c.63G>A p.L21= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV51470068; called by muse, mutect2, varscan2
- CASK | c.1272C>T p.D424= | Silent (SNP) | VAF 40/206 reads (19%) | catalogued as rs756399346, COSV59376417; called by muse, mutect2, varscan2
- CCDC96 | c.1554C>T p.T518= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV59509757; called by muse, mutect2, varscan2
- CCR6 | c.927C>T p.C309= | Silent (SNP) | VAF 25/183 reads (14%) | catalogued as COSV59475900; called by muse, mutect2, varscan2
- CD82 | c.672G>A p.L224= | Silent (SNP) | VAF 8/121 reads (7%) | catalogued as rs1055366914, COSV57037764; called by muse, mutect2
- CDC42BPA | c.1569A>G p.L523= | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as rs747432755, COSV62023422; called by muse, mutect2, varscan2
- CDH4 | c.1215C>T p.R405= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs568480999, COSV64677140; called by muse, mutect2, varscan2
- CETN1 | c.393C>T p.N131= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs933957984, COSV59122268; called by muse, mutect2, varscan2
- CFAP43 | c.945C>T p.G315= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs572361665, COSV53381903; called by muse, mutect2, varscan2
- CIDEB | c.603T>C p.R201= | Silent (SNP) | VAF 8/89 reads (9%) | catalogued as rs1261065663, COSV51868354; called by muse, mutect2
- CIT | c.978T>C p.D326= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV55885206; called by muse, mutect2, varscan2
- COL5A1 | c.1293G>A p.G431= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as CD129004, COSV65675834; called by muse, mutect2
- CTNNBL1 | c.796C>T p.L266= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV63747641; called by muse, mutect2, varscan2
- DDX60 | c.177G>A p.G59= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1385154871, COSV67099646; called by muse, mutect2, varscan2
- DGKH | c.792C>T p.C264= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs147508042; called by muse, mutect2, varscan2
- DIPK2B | c.720C>A p.S240= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV67641803; called by muse, mutect2
- ECE1 | c.387C>A p.A129= | Silent (SNP) | VAF 54/242 reads (22%) | catalogued as COSV51671341; called by muse, mutect2, varscan2
- EIF3A | c.3300G>A p.R1100= | Silent (SNP) | VAF 40/206 reads (19%) | catalogued as rs1179583966, COSV64963726; called by muse, mutect2, varscan2
- EML3 | c.126C>T p.R42= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV53884822; called by muse, mutect2
- EPHB3 | c.1533C>T p.D511= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1281322000, COSV57809635; called by muse, mutect2
- EXT1 | c.1644C>T p.S548= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV65485720; called by muse, mutect2, varscan2
- FAM117B | c.1575G>A p.P525= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs374560975, COSV57422783; called by muse, varscan2
- FAM83B | c.114C>T p.H38= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs1233545285, COSV60927567; called by muse, mutect2, varscan2
- FASN | c.7464C>T p.S2488= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs1163971329, COSV60762017; called by muse, mutect2, varscan2
- FBLN5 | c.756C>T p.S252= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV50910475; called by muse, mutect2
- FGGY | c.933C>T p.G311= | Silent (SNP) | VAF 58/209 reads (28%) | catalogued as rs1161182007, COSV58035342; called by muse, mutect2, varscan2
- GM2A | c.531T>C p.S177= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV64095921; called by muse, mutect2, varscan2
- HIRA | c.177T>A p.I59= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV54280663; called by muse, mutect2, varscan2
- HRNR | c.1353C>T p.S451= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as rs1478144201, COSV64263500; called by muse, mutect2, varscan2
- IFNA7 | c.537A>G p.T179= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs777325341, COSV53332446; called by muse, mutect2, varscan2
- IKBKB | c.1803C>T p.F601= | Silent (SNP) | VAF 57/198 reads (29%) | catalogued as rs200019365, COSV60600151; called by muse, mutect2, varscan2
- INTS1 | c.1330T>C p.L444= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV67180100; called by muse, mutect2, varscan2
- INTS3 | c.2628G>A p.L876= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs754316597, COSV55166056; called by muse, mutect2, varscan2
- IPO13 | c.1440T>C p.I480= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV64895331; called by muse, mutect2, varscan2
- IQCC | c.943C>T p.L315= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV52208625; called by muse, mutect2, varscan2
- IQSEC3 | c.2157C>T p.C719= (on ENST00000538872 / NM_001170738.2; = p.C416= on NM_015232.1) | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs782243162, COSV58290756; called by muse, mutect2
- ITGB4 | c.4530C>T p.Y1510= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV52333861; called by muse, mutect2
- ITIH6 | c.2517C>T p.H839= | Silent (SNP) | VAF 45/261 reads (17%) | catalogued as COSV54495517, COSV54495602; called by muse, mutect2, varscan2
- ITPR1 | c.3042C>T p.S1014= (on ENST00000354582; = p.S999= on NM_002222.7) | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as rs762618794, COSV57006672; called by muse, mutect2, varscan2
- JMJD1C | c.1269A>G p.G423= | Silent (SNP) | VAF 53/218 reads (24%) | catalogued as COSV67868028; called by muse, mutect2, varscan2
- KBTBD2 | c.49T>C p.L17= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV58364449; called by muse, mutect2, varscan2
- KCNH6 | c.189C>A p.P63= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV59008247; called by muse, mutect2
- KCNU1 | c.3186A>G p.A1062= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV67760264; called by muse, mutect2, varscan2
- KIF18B | c.1005C>T p.Y335= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as rs375751581, COSV59273560; called by muse, mutect2
- KIF1A | c.2505C>T p.T835= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs370648599; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KIRREL1 | c.2154G>A p.R718= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV63291969; called by muse, mutect2
- KRTAP10-10 | c.39C>T p.C13= | Silent (SNP) | VAF 20/198 reads (10%) | catalogued as COSV59966851; called by muse, mutect2, varscan2
- KRTAP19-1 | c.186C>T p.Y62= | Silent (SNP) | VAF 31/167 reads (19%) | catalogued as rs571502343; called by muse, mutect2, varscan2
- LARP7 | c.1716G>A p.A572= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs763919425, COSV60522452; called by muse, mutect2, varscan2
- LDLR | c.1251C>T p.S417= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs763449261, COSV52942433; called by muse, mutect2
- LRIG1 | c.2037T>C p.G679= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV56249218; called by muse, varscan2
- MAST4 | c.3351G>A p.S1117= (on ENST00000403625 / NM_001164664.2; = p.S928= on NM_015183.3) | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as rs1483162197, COSV55144484; called by muse, mutect2, varscan2
- MDGA1 | c.234C>T p.S78= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs758378803, COSV51802467; called by muse, mutect2
- MXI1 | c.630T>C p.S210= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs1468342856, COSV53293680; called by muse, mutect2, varscan2
- MYH13 | c.4245C>T p.C1415= | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as rs368930513, COSV52844819; called by muse, mutect2, varscan2
- MYLK | c.1119G>A p.R373= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as COSV60624162; called by muse, mutect2
- NCKAP5 | c.2172T>C p.A724= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV58478687; called by muse, mutect2, varscan2
- NCOR1 | c.3930T>C p.D1310= | Silent (SNP) | VAF 45/218 reads (21%) | catalogued as rs772888503, COSV51999293; called by muse, mutect2, varscan2
- NEK6 | c.939C>A p.T313= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV52333074; called by muse, mutect2
- NLRP13 | c.252G>T p.V84= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs1011969073, COSV61624356; called by muse, mutect2, varscan2
- NOA1 | c.2007G>A p.Q669= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV51739024; called by muse, mutect2, varscan2
- NOTCH2 | c.1524G>A p.Q508= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV56708304; called by muse, mutect2, varscan2
- NR1I2 | c.528G>T p.G176= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV61979865; called by muse, mutect2
- NR3C2 | c.1026C>T p.S342= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV61000855; called by muse, mutect2, varscan2
- NUAK1 | c.1383G>A p.T461= | Silent (SNP) | VAF 41/171 reads (24%) | catalogued as rs753985820, COSV54608962; called by muse, mutect2, varscan2
- OBSCN | c.6912G>A p.K2304= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV52837383; called by muse, mutect2
- ORAI1 | c.450G>A p.A150= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs782232478, COSV57492544; called by muse, mutect2
- PABPC1 | c.1518C>T p.R506= | Silent (SNP) | VAF 3/64 reads (5%) | catalogued as COSV59408535; called by muse, mutect2
- PAPPA | c.1344C>T p.F448= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs145700256; called by muse, mutect2
- PAPPA | c.4341C>A p.A1447= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV60293078; called by muse, mutect2, varscan2
- PDZRN4 | c.2943C>G p.G981= (on ENST00000402685 / NM_001164595.2; = p.G723= on NM_013377.4) | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV54219127; called by muse, mutect2, varscan2
- PGBD5 | c.1299C>T p.S433= (on ENST00000525115; = p.S502= on NM_001258311.2) | Silent (SNP) | VAF 37/155 reads (24%) | catalogued as COSV58414058; called by muse, mutect2, varscan2
- PHETA2 | c.666C>A p.S222= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV58791590; called by muse, mutect2, varscan2
- PHF2 | c.1977C>T p.F659= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs373035320; called by muse, mutect2, varscan2
- PHKA1 | c.1869T>C p.P623= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV59812444; called by muse, mutect2, varscan2
- PKD1L2 | c.2730T>C p.H910= | Silent (SNP) | VAF 10/113 reads (9%) | catalogued as COSV55172389; called by muse, mutect2
- PPARGC1A | c.738G>A p.S246= | Silent (SNP) | VAF 95/467 reads (20%) | catalogued as COSV53534264; called by muse, mutect2, varscan2
- PROC | c.657G>A p.R219= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV52168710; called by muse, mutect2, varscan2
- PTK7 | c.2838G>A p.V946= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV57852157; called by muse, mutect2, varscan2
- RALGAPA2 | c.561T>C p.Y187= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV52513114; called by muse, mutect2, varscan2
- RANGAP1 | c.1182G>A p.E394= | Silent (SNP) | VAF 35/184 reads (19%) | catalogued as rs1336762190, COSV62364927; called by muse, mutect2, varscan2
- RBM10 | c.2577C>T p.D859= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV61312673; called by muse, varscan2
- RBP1 | c.407G>A p.*136= (on ENST00000619087 / NM_001365940.2; = p.*198= on NM_002899.5) | Silent (SNP) | VAF 10/123 reads (8%) | catalogued as COSV51678795; called by muse, mutect2
- RFX6 | c.2538C>T p.D846= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV60589243; called by muse, mutect2, varscan2
- RHBDF1 | c.345G>A p.K115= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV51958438; called by muse, mutect2
- RLBP1 | c.921C>T p.G307= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as COSV51529619; called by muse, mutect2, varscan2
- RUSC1 | c.1825T>C p.L609= (on ENST00000368352 / NM_001105203.2; = p.L140= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 45/374 reads (12%) | catalogued as rs778216611, COSV52743191; called by muse, mutect2, varscan2
- SCN1B | c.252G>A p.E84= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as rs761825754, COSV52896136; called by muse, mutect2, varscan2
- SCP2 | c.375T>C p.S125= | Silent (SNP) | VAF 61/264 reads (23%) | catalogued as COSV65262769; called by muse, mutect2, varscan2
- SECISBP2L | c.96T>C p.P32= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV55938414; called by muse, mutect2, varscan2
- SH3BP2 | c.762C>A p.S254= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV62555616; called by muse, mutect2
- SH3PXD2A | c.1701A>G p.S567= (on ENST00000369774 / NM_001365079.1; = p.S539= on NM_014631.2) | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV60121067; called by muse, mutect2, varscan2
- SIT1 | c.396G>A p.L132= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs772622575, COSV52399939, COSV52400476; called by muse, mutect2, varscan2
- SLC27A6 | c.615G>A p.V205= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV52488445; called by muse, mutect2, varscan2
- SRRM4 | c.1338C>T p.S446= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV57429314; called by muse, mutect2, varscan2
- TAFA2 | c.138G>T p.V46= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV69184902; called by muse, mutect2
- TARS3 | c.354C>T p.S118= | Silent (SNP) | VAF 36/227 reads (16%) | catalogued as rs756830860, COSV60109857; called by muse, mutect2, varscan2
- TDRD6 | c.1719C>T p.G573= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV60179266; called by muse, mutect2, varscan2
- TFAP2D | c.294G>A p.S98= | Silent (SNP) | VAF 59/295 reads (20%) | catalogued as COSV50408104, COSV50443394; called by muse, mutect2, varscan2
- TRAF2 | c.537C>T p.H179= | Silent (SNP) | VAF 29/132 reads (22%) | catalogued as rs761593278, COSV56042003; called by muse, mutect2, varscan2
- TRAPPC10 | c.2985G>A p.T995= | Silent (SNP) | VAF 55/258 reads (21%) | catalogued as COSV52381641; called by muse, mutect2, varscan2
- TRIM58 | c.1099C>T p.L367= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as COSV63572506; called by muse, mutect2
- TRO | c.3489T>C p.S1163= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as COSV51508756; called by muse, mutect2
- TSSK4 | c.45C>A p.A15= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as COSV55305412; called by muse, mutect2
- UBR2 | c.4356C>T p.H1452= | Silent (SNP) | VAF 43/184 reads (23%) | catalogued as rs1449498713, COSV65752988; called by muse, mutect2, varscan2
- ULK4 | c.3477C>T p.S1159= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV57225653; called by muse, mutect2
- USP29 | c.2469C>T p.Y823= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV54147227; called by muse, mutect2, varscan2
- USP42 | c.1275C>A p.T425= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as COSV60364879; called by muse, mutect2, varscan2
- ZNF407 | c.423T>C p.D141= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as COSV55272502; called by muse, mutect2, varscan2
- ZNF578 | c.711C>T p.G237= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs749553422, COSV69736578; called by muse, mutect2, varscan2
- ZNF766 | c.441G>A p.S147= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs770516942, COSV63010397; called by muse, mutect2, varscan2
- ZP2 | c.999G>A p.Q333= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV54817285; called by muse, mutect2, varscan2
- ZSWIM1 | c.142C>T p.L48= | Silent (SNP) | VAF 42/212 reads (20%) | catalogued as COSV54852093; called by muse, mutect2, varscan2
- C9orf129 | n.545C>A | RNA (SNP) | VAF 31/103 reads (30%) | catalogued as COSV64882281; called by muse, mutect2, varscan2
- CTAG2 | c.*62C>T | 3'UTR (SNP) | VAF 17/300 reads (6%) | catalogued as COSV99908971; called by muse, mutect2
- DST | c.4296+3846G>T | Intron (SNP) | VAF 5/79 reads (6%) | catalogued as COSV99756296; called by muse, mutect2
- HAS3 | chr16:69118443 A>G | 3'Flank (SNP) | VAF 12/141 reads (9%) | catalogued as COSV54709495; called by muse, mutect2
- KCNMB3 | c.69-46T>C | Intron (SNP) | VAF 25/130 reads (19%) | catalogued as COSV100046573; called by muse, mutect2, varscan2
- MCF2L | c.170-35091C>T | Intron (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100983474; called by muse, mutect2
- MIR519D | n.29C>T | RNA (SNP) | VAF 25/125 reads (20%) | catalogued as rs550303151; called by muse, mutect2, varscan2
- NOP56 | c.1282-92del | Intron (DEL) | VAF 34/150 reads (23%) | catalogued as rs1256538354; called by mutect2, pindel, varscan2
- PAX3 | chr2:222303937 C>T | 5'Flank (SNP) | VAF 33/90 reads (37%) | catalogued as COSV54676937; called by muse, mutect2, varscan2
- RNFT2 | c.*3220A>C | 3'UTR (SNP) | VAF 27/252 reads (11%) | catalogued as COSV99984791; called by muse, mutect2, varscan2
- SPAG8 | c.*916T>C | 3'UTR (SNP) | VAF 22/290 reads (8%) | catalogued as rs143258253; called by muse, mutect2
- WASF4P | n.512T>C | RNA (SNP) | VAF 45/530 reads (8%) | called by muse, mutect2
